Surgical pathology report (de-identified scan), TCGA case TCGA-CG-5719, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-5719-01A (Primary Tumor).

Diagnosis:

Highly differentiated invasive gastric adenocarcinoma of the intestinal type with infiltration of all wall layers of the attached loop of colon, of the separately submitted colon segment, of the organ capsule of the pancreas with marked perineural tumor growth in parts and with a metastasis of the tumor in a pericolic lymph node and three peripancreatic lymph nodes, all with tumor-free resection margins, and tumor-free jointly resected hepatic and splenic parenchyma. The regional lymph nodes of the adjacent fatty tissue of the greater and lesser curvature of the stomach (N = 7), the hepatoduodenal region (N = 1), and from the area of the common hepatic artery (N = 7) were all tumor-free.

Tumor classification:

M 8140/3, ■■■, pT4, pN0, ■■■■.

Source: NCI Genomic Data Commons file 62150dc9-9a5c-47cb-9239-a634bc3cb31a (TCGA-CG-5719.EB918BCF-D1F0-4FB1-8829-743BBE25AD6F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).